Somatic mutation profile of tumor specimen TCGA-J2-8192-01A (aliquot TCGA-J2-8192-01A-11D-2238-08) from TCGA case TCGA-J2-8192, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.4 years (23,892 days).
Specimen TCGA-J2-8192-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecae4d1a-76a0-40a8-9f83-ec7412f89fe5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J2-8192-10A (Blood Derived Normal), aliquot TCGA-J2-8192-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5877a051-fc2f-4e02-b49b-b32ad032f948

The open-access MAF lists 78 somatic variants for this specimen: 57 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 17, Nonsense Mutation 5, Intron 3, Frame Shift Ins 1, In Frame Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 42/128 reads (33%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- ADCY8 | c.3127G>A p.V1043M | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs371947731; called by muse, mutect2, varscan2
- ALLC | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs750935372, COSV52994991; called by muse, mutect2, varscan2
- ANKRD52 | c.625C>G p.L209V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV57284791; called by muse, mutect2, varscan2
- ARHGEF40 | c.4040G>A p.R1347Q | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.173); catalogued as rs747491677, COSV53880931; called by muse, mutect2, varscan2
- ASTN1 | c.845C>G p.S282W | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.328); catalogued as COSV56071186, COSV56088092, COSV56090953; called by muse, mutect2
- ATP8B3 | c.3187G>T p.E1063* | Nonsense Mutation (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100034024; called by muse, mutect2, varscan2
- B3GAT3 | c.79C>G p.L27V | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV99641790; called by muse, mutect2
- C8A | c.427T>A p.Y143N | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV63484583; called by muse, mutect2
- CARD8 | c.914T>C p.I305T (on ENST00000651546 / NM_001184900.3; = p.I255T on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.677); catalogued as COSV62873723; called by muse, mutect2, varscan2
- CASP8 | c.512T>G p.L171R (on ENST00000432109 / NM_033355.3; = p.L203R on NM_001228.4) | Missense Mutation (SNP) | VAF 22/279 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51852186; called by muse, mutect2
- CBLL2 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.045); catalogued as rs371087148, COSV60369056; called by muse, mutect2, varscan2
- CLEC4F | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV55479764; called by muse, mutect2, varscan2
- CUBN | c.3446A>G p.D1149G | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV64717406; called by muse, mutect2, varscan2
- CWC22 | c.2105A>G p.D702G | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV55429113; called by muse, mutect2, varscan2
- DENND2A | c.2505+1G>T p.X835_splice | Splice Site (SNP) | VAF 4/16 reads (25%) | catalogued as COSV99325552; called by muse, mutect2
- DNAH14 | c.1022T>A p.F341Y (on ENST00000445597; = p.F214Y on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.031); catalogued as COSV64781516; called by muse, mutect2, varscan2
- EPHA10 | c.1504C>A p.Q502K | Missense Mutation (SNP) | VAF 8/235 reads (3%) | SIFT tolerated (0.35); PolyPhen benign (0.079); catalogued as COSV57624468; called by muse, mutect2
- FN3KRP | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs771035632, COSV53929195; called by muse, mutect2, varscan2
- FRMPD1 | c.856C>T p.Q286* | Nonsense Mutation (SNP) | VAF 30/92 reads (33%) | catalogued as COSV66700622; called by muse, mutect2, varscan2
- HNRNPAB | c.398A>G p.H133R | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.828); catalogued as COSV57424486; called by muse, mutect2, varscan2
- HR | c.2776C>T p.L926F | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.079); catalogued as rs375878986; called by muse, mutect2, varscan2
- IRF2BPL | c.1040A>G p.K347R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.758); catalogued as rs147723826; called by muse, mutect2, varscan2
- LMO7 | c.4480G>A p.E1494K (on ENST00000357063; = p.E1175K on NM_005358.5) | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774848818, COSV58542743; called by muse, mutect2, varscan2
- MIB2 | c.684C>G p.D228E | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61755952; called by muse, mutect2, varscan2
- N4BP2 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 18/136 reads (13%) | catalogued as COSV54700948, COSV54702590; called by mutect2, varscan2
- NAT10 | c.2551C>G p.L851V | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.425); catalogued as rs1329369124, COSV57664239; called by muse, mutect2, varscan2
- NR0B1 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.037); catalogued as COSV66764162, COSV66764198; called by muse, mutect2, varscan2
- OLFML2B | c.1778G>A p.R593H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs148462010; called by muse, mutect2, varscan2
- OR1S1 | c.886C>G p.P296A | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58707373; called by muse, mutect2, varscan2
- PAMR1 | c.1368G>T p.K456N (on ENST00000619888 / NM_001001991.3; = p.K473N on NM_015430.4) | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.109); catalogued as COSV53513193; called by muse, mutect2
- PBOV1 | c.143T>A p.F48Y | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.063); catalogued as COSV52459255; called by muse, mutect2
- PCDHB6 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 32/177 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs1554277384, COSV50700447; called by muse, mutect2, varscan2
- PPP1R9B | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.572); catalogued as COSV57541567; called by muse, mutect2, varscan2
- PRDM5 | c.1222G>T p.E408* | Nonsense Mutation (SNP) | VAF 16/126 reads (13%) | catalogued as COSV53361511; called by muse, mutect2
- PRUNE2 | c.7999G>A p.G2667S | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770780350, COSV65042243; called by muse, mutect2, varscan2
- RAF1 | c.1937C>T p.P646L | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV50105303; called by muse, mutect2, varscan2
- RBM15 | c.2047C>T p.R683C | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.725); catalogued as COSV63923351; called by muse, mutect2, varscan2
- RPE | c.116T>G p.M39R | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV55893358; called by muse, mutect2, varscan2
- SAMD9L | c.2338C>A p.Q780K | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV59082131; called by muse, mutect2
- SAP18 | c.401A>G p.D134G (on ENST00000607003; = p.D153G on NM_005870.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/273 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV66822771; called by muse, mutect2, varscan2
- SGPP1 | c.691C>A p.L231I | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV99905704, COSV99905940; called by mutect2, varscan2
- SLC22A7 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.044); catalogued as COSV65354623; called by muse, mutect2, varscan2
- SLC35F4 | c.28C>T p.H10Y | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV60265154; called by muse, mutect2, varscan2
- SLC38A6 | c.1095C>A p.F365L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV99959458, COSV99960137; called by muse, mutect2, varscan2
- SLC6A9 | c.2080G>A p.G694S (on ENST00000360584 / NM_201649.4; = p.G640S on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/211 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.093); catalogued as COSV62210943; called by muse, mutect2, varscan2
- SMAD4 | c.766C>T p.Q256* | Nonsense Mutation (SNP) | VAF 4/60 reads (7%) | catalogued as COSV61686540, COSV61686776; called by muse, mutect2
- SPATA20 | c.507G>T p.W169C (on ENST00000356488 / NM_001258372.1; = p.W185C on NM_022827.4) | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV50066948; called by muse, mutect2, varscan2
- STYXL1 | c.338G>A p.G113D | Missense Mutation (SNP) | VAF 68/253 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as COSV50389447; called by muse, mutect2, varscan2
- SYT9 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.04); catalogued as rs748814240, COSV59619395; called by mutect2, varscan2
- TBC1D14 | c.264G>T p.R88S | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.115); catalogued as COSV68986058; called by muse, mutect2, varscan2
- TRMT6 | c.968C>T p.T323I | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1347412275, COSV52543952; called by muse, mutect2, varscan2
- UBE2O | c.2006C>T p.A669V | Missense Mutation (SNP) | VAF 65/334 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV60063802; called by muse, mutect2, varscan2
- ZNF14 | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.975); catalogued as COSV59849889; called by muse, mutect2, varscan2
- ZNF445 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs761608124, COSV68538981; called by muse, mutect2, varscan2
- ZNFX1 | c.1159G>C p.G387R | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1219552985, COSV65575831; called by muse, mutect2, varscan2
- AP2M1 | c.264dup p.M89Dfs*22 | Frame Shift Ins (INS) | VAF 15/140 reads (11%) | called by mutect2, varscan2
- ABCC12 | c.2682G>A p.K894= | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as COSV60914020; called by muse, mutect2, varscan2
- BMP10 | c.1032G>A p.P344= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as rs1397703638, COSV54895223, COSV54896450; called by muse, mutect2, varscan2
- CAMSAP1 | c.1176G>A p.A392= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1227635830, COSV56723429; called by muse, mutect2, varscan2
- FBXO44 | c.225G>A p.R75= | Silent (SNP) | VAF 41/217 reads (19%) | catalogued as COSV52354356; called by muse, mutect2, varscan2
- FLOT2 | c.903C>T p.A301= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as COSV67529118; called by muse, varscan2
- NUP210L | c.5346G>A p.E1782= | Silent (SNP) | VAF 14/289 reads (5%) | catalogued as COSV55149085; called by muse, mutect2
- OR51F2 | c.831C>A p.I277= | Silent (SNP) | VAF 8/171 reads (5%) | catalogued as COSV100437885; called by muse, mutect2
- OR6F1 | c.777C>T p.H259= | Silent (SNP) | VAF 18/127 reads (14%) | catalogued as rs1047241669, COSV57468087; called by muse, mutect2, varscan2
- PAXIP1 | c.3123C>G p.A1041= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs765151848, COSV66898491; called by muse, mutect2, varscan2
- PPARD | c.819C>G p.L273= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as rs1238302187, COSV61099965; called by muse, mutect2
- PRPF6 | c.1371G>C p.R457= | Silent (SNP) | VAF 38/164 reads (23%) | catalogued as COSV53871771; called by muse, mutect2, varscan2
- SARS1 | c.489A>T p.T163= | Silent (SNP) | VAF 30/191 reads (16%) | catalogued as COSV52321145; called by muse, mutect2, varscan2
- SCN3B | c.501C>A p.V167= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV54799560; called by muse, mutect2
- STAB1 | c.2667C>T p.C889= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as rs1174012525, COSV58737369; called by muse, mutect2, varscan2
- TCERG1 | c.1227C>T p.I409= | Silent (SNP) | VAF 114/475 reads (24%) | catalogued as rs779078980, COSV57037903; called by muse, mutect2, varscan2
- TTN | c.34989G>T p.L11663= (on ENST00000591111; = p.L10736= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/103 reads (8%) | catalogued as COSV100594356; called by muse, mutect2
- WDR44 | c.396G>A p.E132= | Silent (SNP) | VAF 61/226 reads (27%) | catalogued as COSV54164308; called by muse, mutect2, varscan2
- NACA | c.70+4549_70+4550del | Intron (DEL) | VAF 6/42 reads (14%) | called by mutect2, pindel, varscan2
- NACA | c.70+4423C>G | Intron (SNP) | VAF 14/80 reads (18%) | called by mutect2, varscan2
- NACA | c.70+4417_70+4420del | Intron (DEL) | VAF 12/79 reads (15%) | called by mutect2, pindel, varscan2
- SSPOP | n.6456C>G | RNA (SNP) | VAF 24/94 reads (26%) | catalogued as COSV50487792; called by muse, mutect2, varscan2
